Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A410, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A410-01A (Primary Tumor).

ICD-O3
Carcinoma, Squamous cell, NOS
8070/3

Site: Cervix, NOS
C53.9

7-20-12
K20

Path Report: CERVIX TISSUE CHECKLIST

Specimen type: Hysterectomy, bilateral salpingo-oophorectomy

Tumor site: Cervix

Tumor size: 8 x 5 x 4 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Stromal invasion from 3.0 mm to 5.0 mm

Lymph nodes: 0/14 positive for metastasis (Regional 0/14)

Lymphatic invasion: Absent

Venous invasion: Absent

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Source: NCI Genomic Data Commons file ccb29301-462e-4a57-9294-63f8059344e1 (TCGA-EA-A410.EA3DC9B0-2680-4F3C-B14A-05CB047305BD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).